Somatic mutation profile of tumor specimen 0DSI9D from CCDI case PBBNVL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Fibrosarcoma, NOS; Tissue or organ of origin: Other ill-defined sites; Age at diagnosis: 19.4 years (7,082 days).
Specimen 0DSI9D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 705e9120-46ba-49f7-9a47-f2c4b2c1e56c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSI80 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ede6632-ff25-4c1c-8add-3bfd4999d417

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3565C>T p.R1189* | Nonsense Mutation (SNP) | VAF 85/444 reads (19%) | hotspot (GDC flag); catalogued as rs267607070, CM101016, COSV60786775, COSV60811967; ClinVar: pathogenic; called by muse, varscan2
- ANK3 | c.3380C>T p.T1127M (on ENST00000280772 / NM_001320874.2; = p.T261M on NM_001149.3) | Missense Mutation (SNP) | VAF 152/580 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248267868, COSV99781224; called by muse, varscan2
- CACTIN | c.1356-8C>T | Splice Region (SNP) | VAF 40/104 reads (38%) | called by muse, varscan2
- PHLDB2 | c.3641C>T p.T1214I (on ENST00000393925 / NM_001134439.2; = p.T1171I on NM_145753.2) | Missense Mutation (SNP) | VAF 298/715 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- UHRF1BP1L | c.3904G>A p.E1302K | Missense Mutation (SNP) | VAF 172/491 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TLN1 | c.6246C>T p.N2082= | Silent (SNP) | VAF 144/352 reads (41%) | catalogued as rs11541906, COSV59207920; called by muse, varscan2
- ZNF239 | c.885G>A p.K295= | Silent (SNP) | VAF 124/297 reads (42%) | catalogued as rs370581500; called by muse, varscan2
- RYR3 | c.10023+96A>G | Intron (SNP) | VAF 66/170 reads (39%) | called by muse, varscan2
